CGCI case HTMCP-01-07-00336 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b0dde080-bbae-4933-ac48-f5f36c78d3fa

Demographics
Sex at birth: male; Race: black or african american; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 34.2 years (12,508 days); Year of diagnosis: 2015; Method of diagnosis: Biopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 722 days (2.0 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Soft tissue (muscle, ligaments, subcutaneous); Sites of involvement: Bone, NOS / Bone marrow / Soft tissue / Colon, NOS.
   Pathology details: Lymph node involved site: Retroperitoneal.
   Pathology details: Lymph node involved site: Mesenteric.
   Pathology details: Additional pathology findings: Percent follicular component <= 10%; Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Tumor largest dimension diameter: 133 cm.
   Pathology details: Lymph node involved site: Supraclavicular.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (6 entries)
- Days to follow up: 0 days; ECOG performance status: 1.
- Days to follow up: 76 days; Disease response: With Tumor.
- Days to follow up: 365 days (1.0 years); Disease response: Tumor Free; Imaging type: PET; Imaging result: Negative.
- Days to follow up: 680 days (1.9 years); Imaging type: PET; Imaging result: Negative.
- Days to follow up: 722 days (2.0 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -773.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Equivocal.
- BCL2 (IHC): Positive.
- BCL6 (FISH): Normal.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Equivocal.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Equivocal; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- TP53 (IHC): Positive; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus: Negative.
- Epstein-Barr Virus (ISH): Negative.
- Lactate Dehydrogenase 622 [Blood test normal range upper: 250].

Other clinical attributes
- Day -773: Comorbidities: HIV/AIDS.
- Day -773: Risk factors: HIV/AIDS.
- Day 0: Weight: 89.1 kg; Height: 188 cm; BMI: 25.2; CD4 count: 304; Haart treatment indicator: Yes; HIV viral load: 25.
- Day 0: Cdc hiv risk factors: Homosexual Contact.
- Day 76: Nadir CD4 count: 283.

Biospecimens (3 samples)
- Sample HTMCP-01-07-00336-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-07-00336-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-07-00336-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; Lost to follow-up: No.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- History of disease: Year of HIV diagnosis: 2012; Haart therapy prior to diagnosis: Yes; Haart therapy at diagnosis: Yes; Cdc HIV risk group: Homosexual or bisexual contact.
- Primary pathology: Follicular component percent: < or = 10%; Extranodal site involvement: 4; Method initial path diagnosis: Biopsy (all types); Bone marrow sample histology: Concordant Histology.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Bone; Submitted tumor site: Bone Marrow; Submitted tumor site: Soft Tissue (muscle  ligaments  subcutaneous); Submitted tumor site: Colon.
- Tests performed: LDH level: 622.
- Tests performed, Genetic testing results, Genetic testing result 1: Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 3: Genetic abnormality tested: BCL6.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-07-00336-01A-01E-11051:
- % tumour top: 75
- % tumour bottom: 75

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220304.xlsx, for sample HTMCP-01-07-00336-01A-01S-11051:
- % tumour top: 75
- % tumour bottom: 75
